Gene-level copy-number profile of tumor specimen TCGA-D1-A3JP-01A from TCGA case TCGA-D1-A3JP, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 61.7 years (22,538 days).
Specimen TCGA-D1-A3JP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.82de897e-d9cd-4e1a-84ba-6b036a71933f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D1-A3JP-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/83a5fda6-f367-451d-abda-1624387cf31e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 2,500; copy number 2: 23,336; copy number 3: 16,166; copy number 4: 17,069; copy number 5: 107; copy number 6: 129; copy number 7: 10; copy number 8: 300; copy number 10: 49; copy number 11: 15; copy number 12: 62; copy number 18: 11; copy number 20: 7; copy number 37: 21; copy number 40: 9; copy number 41: 18.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-D1-A3JP-01): tumor purity 0.44, ploidy 2.89, whole-genome doublings 1 (call status: snp_call).

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,703,606–59,703,703, 1 gene: MIR582.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 738 genes in 32 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,711,277–31,095,558, 15 genes, copy number 5: MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778, RN7SKP91, AL445235.1, SDC3, RN7SL371P, PUM1, AL356320.2, AL356320.1, SELENOWP1.
- chr1:39,692,182–39,944,998, 15 genes, copy number 6 (within-gene range 3–6): PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA.
- chr1:48,050,659–48,182,428, 5 genes, copy number 5 (within-gene range 3–5): LINC02794, AL356289.1, CYP46A4P, SKINT1L, AL356289.2.
- chr1:151,540,305–151,953,985, 31 genes, copy number 5: TUFT1, AL365436.2, MIR554, AL365436.1, SNX27, AL391335.1, RNU6-1062P, CELF3, AL589765.1, RIIAD1, RNU6-662P, AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4, RORC, C2CD4D, Y_RNA, C2CD4D-AS1, THEM5, THEM4, AL450992.2, AL450992.3, KRT8P28.
- chr1:204,064,533–204,377,665, 11 genes, copy number 5 (within-gene range 4–5): AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3.
- chr1:222,815,022–223,395,465, 9 genes, copy number 40 (within-gene range 4–40): DISP1, NDUFB1P2, AL929091.1, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185.
- chr1:223,947,605–224,379,459, 18 genes, copy number 41: CICP5, GTF2IP20, RNU6-1319P, AC138393.1, AC138393.3, AC138393.2, RN7SKP49, FBXO28, AC092809.3, DEGS1, SNORA72, AC092809.2, AC092809.4, NVL, MIR320B2, AC092809.1, RNU6-1008P, CNIH4.
- chr2:7,576,841–7,737,095, 6 genes, copy number 6: RNU6ATAC37P, AC092580.4, AC092580.2, LINC01871, AC092580.3, AC092580.1.
- chr2:9,583,967–10,090,319, 19 genes, copy number 6: YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B, AC010969.2, AC010969.3, GRHL1, AC010969.1, AC104794.4, AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1.
- chr2:173,811,076–174,027,163, 6 genes, copy number 6: AC106900.1, RPL5P7, SP3, AC016737.1, AC016737.2, LINC01960.
- chr3:100,910,975–101,320,575, 4 genes, copy number 6: AC080014.1, RNU6-865P, ACTR3P3, IMPG2.
- chr3:101,357,292–101,359,242, 1 gene, copy number 6: ZNF90P1.
- chr6:41,267,926–41,736,259, 15 genes, copy number 5: TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1.
- chr6:135,851,701–136,195,574, 1 gene, copy number 5 (within-gene range 3–5): PDE7B.
- chr6:135,991,936–136,336,087, 7 genes, copy number 5 (within-gene range 3–5): AL138828.1, COX5BP2, AL138828.2, MTFR2, BCLAF1, AL023284.1, AL023284.4.
- chr6:136,364,129–136,365,079, 1 gene, copy number 5: AL023284.3.
- chr12:31,111,652–31,369,301, 10 genes, copy number 6 (within-gene range 4–6): AC024940.1, AC024940.4, AC024940.2, MREGP1, AC024940.5, SINHCAF, AC024940.3, FLJ13224, LINC02387, U6.
- chr12:31,396,390–31,477,987, 4 genes, copy number 6: RNU6-618P, AC068792.1, AC022080.1, AC022080.2.
- chr12:51,951,699–52,108,261, 10 genes, copy number 7 (within-gene range 4–7): ACVR1B, RNU6-574P, TAMALIN, NR4A1, NR4A1AS, ATG101, AC025259.1, SMIM41, OR7E47P, AC078864.1.
- chr15:66,860,303–67,065,268, 5 genes, copy number 5 (within-gene range 3–5): AC110048.2, AC093334.1, LINC02206, AC087482.1, HMGN2P47.
- chr17:39,566,915–39,977,768, 21 genes, copy number 37: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7, IKZF3, KRT8P34, AC090844.1, ZPBP2, GSDMB, ORMDL3, AC090844.2, LRRC3C, GSDMA.
- chr17:67,611,277–77,500,596, 289 genes, copy number 8–12 (broad region; genes not listed).
- chr19:5,158,495–5,340,803, 4 genes, copy number 12: PTPRS, AC022517.1, RPL32P34, AC005790.1.
- chr19:12,995,475–13,953,392, 32 genes, copy number 8–11: NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A, CCDC130, MRI1, AC008686.1, C19orf53, ZSWIM4, AC020916.2, RN7SL619P, AC020916.1, MIR24-2, MIR27A, MIR23A, NANOS3, MIR181C, MIR181D, C19orf57, CC2D1A, PODNL1.
- chr19:29,775,504–34,832,869, 119 genes, copy number 10–20 (broad region; genes not listed).
- chr22:19,756,703–20,208,524, 26 genes, copy number 6: TBX1, GNB1L, AC000089.1, RTL10, TXNRD2, AC000078.1, COMT, MIR4761, ARVCF, TANGO2, MIR185, AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896.
- chr22:24,806,169–24,946,695, 3 genes, copy number 6 (within-gene range 4–6): SGSM1, AL049759.1, TMEM211.
- chr22:25,009,685–25,051,966, 3 genes, copy number 6: AL022323.2, AL022323.4, AL022323.1.
- chr22:30,291,990–30,674,134, 26 genes, copy number 6 (within-gene range 4–6): TBC1D10A, SF3A1, CCDC157, RNF215, SEC14L2, AC004832.3, AC004832.5, RNU6-564P, AC004832.4, MTFP1, AC004832.6, AC004832.2, SEC14L3, AC004832.1, SDC4P, SEC14L4, SEC14L6, SIRPAP1, GAL3ST1, PES1, AC005006.1, TCN2, SLC35E4, DUSP18, AC003072.1, AC003072.2.
- chr22:30,731,557–30,731,641, 1 gene, copy number 6: MIR3200.
- chr22:42,160,013–42,446,195, 5 genes, copy number 6 (within-gene range 4–6): TCF20, OGFRP1, LINC01315, NFAM1, AL022316.1.
- chr22:46,150,521–47,175,699, 16 genes, copy number 5 (within-gene range 4–5): PPARA, FP325332.1, CDPF1, PKDREJ, TTC38, GTSE1-DT, GTSE1, TRMU, CELSR1, AL031597.1, AL021392.1, GRAMD4, CERK, AL118516.1, TBC1D22A, TBC1D22A-AS1.

Autosomal genes at a single copy (total copy number 1): 2,500. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
